Surgical pathology report (de-identified scan), TCGA case TCGA-B1-A657, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B1-A657-01A (Primary Tumor).

[page 1 of 2]
Collection Date:

FINAL DIAGNOSIS:

PART 1: KIDNEY, RIGHT, INFERIOR LOWER POLE, PARTIAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CLEAR CELL TYPE.
- B. THE TUMOR MEASURES 0.4 CM IN GREATEST DIMENSION.
- C. FUHRMAN NUCLEAR GRADE IS 1 OUT OF 4.
- D. RENAL PARENCHYMAL MARGIN IS NEGATIVE FOR TUMOR.
- E. PATHOLOGICAL STAGE: pT1aNxMx.

PART 2: SOFT TISSUE, FAT OVERLYING TUMOR, BIOPSY - BENIGN FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 3: KIDNEY, RIGHT, PARTIAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, WITH OVERLAPPING FEATURES OF PAPILLARY RENAL CELL CARCINOMA AND MUCINOUS TUBULAR AND SPINDLE CELL CARCINOMA (See Comment).
- B. THE CARCINOMA MEASURES 4.3 CM IN GREATEST DIMENSION.
- C. THE CARCINOMA IS CONFINED TO THE KIDNEY.
- D. LYMPHOVASCULAR INVASION IS NOT IDENTIFIED.
- E. FUHRMAN NUCLEAR GRADE 2/4.
- F. ALL MARGINS ARE NEGATIVE.
- G. PATHOLOGIC STAGE: pT1b NX MX.

COMMENT:

This tumor has an interesting morphology with a papillary architecture but in areas has elongated and angulated tubular growth pattern reminiscent of mucinous and tubular spindle cell carcinoma. No distinct mucin is identified and there are many foam cells in the background. Immunostains were performed and show that tumor cells are positive for CK7 and racemase, focally positive for CD10 and negative for CA(. While we favor this to represent a papillary renal cell carcinoma, our differential diagnosis also includes an unusual variant of mucinous tubular spindle cell carcinoma.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE:	Partial nephrectomy
LATERALITY:	Right
TUMOR SITE:	Not specified
FOCALITY:	Unifocal
TUMOR SIZE:	Greatest dimension: 5.0 cm
MACROSCOPIC EXTENT OF TUMOR:	Tumor limited to kidney
HISTOLOGIC TYPE:	Papillary renal cell carcinoma
HISTOLOGIC GRADE (Fuhrman Nuclear Grade):	G2
PATHOLOGIC STAGING (pTNM):	pT1b pNX Number of regional lymph nodes examined: 0
MARGINS:	pMX Margins uninvolved by invasive carcinoma
ADRENAL GLAND:	Not present
LYMPH-VASCULAR INVASION (LVI):	Absent/not identified
ADDITIONAL PATHOLOGIC FINDINGS:	None identified

4/19/13

Per TSS, papillary = 96%

ICD-O-3

Carcinoma, papillary renal cell 8260/3

Q Kidney NOS C64.9
JW 5/16/13

[page 2 of 2]
SPECIAL PROCEDURES:
In Situ Procedure
Interpretation

SPECIAL PROCEDURE REPORT
MOLECULAR ANATOMIC PATHOLOGY FLUORESCENCE IN SITU HYBRIDIZATION ANALYSIS

Comment: Fluorescent in-situ hybridization (FISH) tests show monosomy of chromosome 1 and 2 in approximately 66% and 54% of the tumor cells. Trisomy of chromosome 17 is seen in 25% of tumor cells.

This FISH profile is suggestive of a mucinous tubular and spindle cell carcinoma. However a papillary renal cell carcinoma cannot be ruled out.

Specimen type: Renal tumor.

Result:	1 Signal	2 Signals	3 or more Signals
CEP1	40 (65.6%)	21 (34.4%)	0 (0%)
CEP2	36 (53.7%)	29 (43.3%)	2 (3.0%)
CEP7	13 (21.3%)	44 (72.1%)	4 (6.6%)
CEP17	11 (18.0%)	35 (57.4%)	15 (24.6%)

Abnormality detected:

Monosomy of chromosome 1 and 2 is seen in approximately 66% and 54% of the tumor cells. Trisomy of chromosome 17 is seen in 25% of tumor cells.

Interpretation guidelines:

Chromosomal losses are considered significant if present in greater than 30% of cells. The loss is indeterminate if present in 20-30% of cases. The loss is considered artifactual if seen in less than 20% of cases.

Chromosomal gains are considered significant if present in greater than 20% of cells. The gain is considered artifactual if seen in less than 20% of cases.

Results

Probes used: CEP1 (1p11.1q11.1), CEP2 (2p11.1q11.2), CEP7 (7p11.1q11.1), CEP17 (17p11.1q11.1).

At least 25 cells are analyzed. The signal distribution for targeted foci of renal carcinoma is recorded. If the test results are not consistent with the clinical findings, and/or diagnostic, a consultation between pathologist and treating physician is warranted.

This test was developed and its performance characteristics determined by the
as required by the CLIA '88 regulations.

Department of Pathology,

References

1. Kovacs G, et al. Cytogenetics of papillary renal cell tumors. Genes Chrom Cancer 3:249-255, 1991.
2. Bugert P, Gaul C, Weber K, Herbers J, Akhtar M, Ljungberg B, Kovacs G. Specific genetic changes of diagnostic importance in chromophobe renal cell carcinomas. Lab Invest. 1997 Feb;76(2):203-8.
3. Hughson MD, Dickman K, Bigler SA, Meloni AM, Sandberg AA. Clear-cell and papillary carcinoma of the kidney: an analysis of chromosome 3, 7, and 17 abnormalities by microsatellite amplification, cytogenetics, and fluorescence in situ hybridization. Cancer Genet Cytogenet. 1998 Oct 15;106(2):93-104.
4. Reuter V & Presti JC. Contemporary approach to the classification of renal epithelial tumors. Semin Oncol 27:124-137, 2000.
5. Salama ME, Worsham MJ, DePeralta-Venturina M. Malignant papillary renal tumors with extensive clear cell change: a molecular analysis by microsatellite analysis and fluorescence in situ hybridization. Arch Pathol Lab Med. 2003 Sep;127(9):1176-81.
6. Brunelli M, Eble JN, Zhang S, Martignoni G, Delahunt B, Cheng L. Eosinophilic and classic chromophobe renal cell carcinomas have similar frequent losses of multiple chromosomes from among chromosomes 1, 2, 6, 10, and 17, and this pattern of genetic abnormality is not present in renal oncocytoma. Mod Pathol 2005; 18 2: 161-169.

Criteria	W 4/19/13	Yes	No

Source: NCI Genomic Data Commons file c56ee82a-b53c-4ba7-a8cb-16f45429ebc3 (TCGA-B1-A657.DE51CCE8-C664-4F04-92C2-367E5270C4B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).